TARGET case TARGET-10-PAPAKJ — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/544c67f2-821b-595f-8f98-0eb65f70559c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 3 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 3.4 years (1,256 days); Year of diagnosis: 2005; Days to last follow up: 2,174 days (6.0 years).
   Treatment given: Protocol identifier: AALL0331.

Follow-up (1 entry)
- Days to follow up: 2,174 days (6.0 years); Event-free: no event (relapse, second malignancy or death) recorded through day 2,174; Year of follow up: 2011.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Positive.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 7.31 ×10³/µL.
- Day 8: Bone Marrow blast count 1%.
- Day 29: Bone Marrow blast count 0%; Minimal Residual Disease (Flow Cytometry) 0%.

Biospecimens (2 samples)
- Sample TARGET-10-PAPAKJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PAPAKJ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_Blast_Data_20230727.xlsx, for sample TARGET-10-PAPAKJ-09A-01D:
- Blast %: >70

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Validation_20230727.xlsx:
- Overall Survival Time in Days: 2174
- WBC at Diagnosis: 7.31
- CNS Status at Diagnosis: CNS 1
- Testicular Involvement: No
- MRD Day 29: 0
- MRD Day 29 Sensitivity: 0.01
- Bone Marrow Site of Relapse: No
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Positive
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 1
- BMA Blasts Day 29: 0
- Karyotype: 47,XY,+21[2]/46,XY[18]
- Down Syndrome: No
- DNA Index: 1
- Cell of Origin: B Cell ALL
